Somatic mutation profile of tumor specimen TCGA-FS-A1ZR-06A (aliquot TCGA-FS-A1ZR-06A-21D-A197-08) from TCGA case TCGA-FS-A1ZR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 36.7 years (13,404 days).
Specimen TCGA-FS-A1ZR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff77e67d-344f-43a6-b285-1db009971d92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZR-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZR-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d28414d-5210-45e4-b70d-6c5af3d5b7c8

The open-access MAF lists 160 somatic variants for this specimen: 108 protein-altering or splice-affecting, 48 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 48, Nonsense Mutation 8, RNA 2, Splice Region 2, Splice Site 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AAMP | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.052); catalogued as COSV50307194; called by muse, mutect2, varscan2
- ABCA9 | c.4349G>A p.G1450E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60622742; called by muse, mutect2, varscan2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by mutect2, varscan2
- ADAMTSL3 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54442280, COSV99720770; called by muse, mutect2, varscan2
- ADH6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756863693, COSV52955529; called by mutect2, varscan2
- ADORA2A | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV58378419; called by muse, mutect2, varscan2
- AP3S2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV60517853; called by muse, mutect2, varscan2
- ARHGAP9 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV62721981; called by mutect2, varscan2
- ATP8B3 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs776734132, COSV59541458; called by mutect2, varscan2
- C2CD2L | c.1504C>T p.L502F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1430088096, COSV60883831; called by muse, mutect2, varscan2
- CCDC105 | c.1184G>A p.R395K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52963615; called by muse, mutect2, varscan2
- CDR1 | c.448A>T p.R150* | Nonsense Mutation (SNP) | VAF 90/118 reads (76%) | catalogued as COSV65164035; called by mutect2, varscan2
- CHD1 | c.1918C>T p.L640F | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52338916; called by muse, varscan2
- COL5A2 | c.567+1G>A p.X189_splice | Splice Site (SNP) | VAF 8/13 reads (62%) | catalogued as COSV66408492; called by muse, mutect2, varscan2
- CORIN | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as rs866164544, COSV56688788; called by muse, mutect2, varscan2
- CRYZ | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV61717381; called by muse, mutect2, varscan2
- CT45A10 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 61/80 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1290230048, COSV65921075, COSV65921153; called by muse, mutect2, varscan2
- CYP17A1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV64004825; called by muse, mutect2, varscan2
- DDX60 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV67095833; called by muse, mutect2, varscan2
- DSC3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1402804256, COSV64572387; called by muse, mutect2, varscan2
- DSP | c.6079G>A p.E2027K | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs762538310, COSV65792113; called by muse, mutect2, varscan2
- EEF2 | c.615C>T p.I205= | Splice Region (SNP) | VAF 19/48 reads (40%) | catalogued as rs375130935, COSV58579656; called by muse, mutect2, varscan2
- EPRS1 | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756764132, COSV65098141; called by muse, mutect2, varscan2
- EVPL | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767324618, COSV56908538; called by mutect2, varscan2
- EXOC6B | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV55549715, COSV55550105; called by muse, varscan2
- FAT3 | c.4370G>A p.G1457D | Missense Mutation (SNP) | VAF 132/349 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.818); catalogued as rs906770525, COSV53093677; called by muse, varscan2
- FAT4 | c.6805C>T p.P2269S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.998); catalogued as rs1284077653, COSV100628651, COSV58677915; called by muse, mutect2, varscan2
- FCRLA | c.85C>T p.L29F (on ENST00000367959; = p.L12F on NM_032738.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV52684928; called by muse, mutect2, varscan2
- FMNL3 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53300065; called by muse, varscan2
- GABRB1 | c.275G>A p.W92* | Nonsense Mutation (SNP) | VAF 32/108 reads (30%) | catalogued as COSV54976365; called by muse, mutect2, varscan2
- GIMAP4 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55431717; called by muse, mutect2, varscan2
- GLIS3 | c.1727C>A p.P576Q | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs559017332, COSV60926833; called by muse, mutect2, varscan2
- GRID2 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 53/136 reads (39%) | catalogued as rs200455027, COSV56183410; called by muse, mutect2, varscan2
- GRID2 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs76699542, COSV56189686; called by muse, varscan2
- GRIN2B | c.3575G>A p.G1192E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as COSV74205405; called by muse, mutect2, varscan2
- HECW2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.07); catalogued as COSV53654288; called by muse, mutect2, varscan2
- HRNR | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765009680, COSV64256268, COSV64261244; called by muse, mutect2, varscan2
- IGLV4-3 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771704349; called by muse, mutect2, varscan2
- IL31RA | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as rs560651126, COSV51680827; called by muse, varscan2
- IL36A | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs866220179, COSV52082919; called by muse, mutect2, varscan2
- ISLR2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62301870; called by muse, mutect2, varscan2
- ITGAL | c.2145G>A p.P715= | Splice Region (SNP) | VAF 23/64 reads (36%) | catalogued as rs200919732, COSV63321159; called by muse, mutect2, varscan2
- ITK | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV70061470; called by muse, mutect2, varscan2
- KRT78 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV58851226; called by mutect2, varscan2
- LAMA2 | c.3754A>G p.K1252E | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV70343644; called by muse, mutect2, varscan2
- LEFTY1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as rs749366481, COSV55282644; called by muse, mutect2, varscan2
- LINGO2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58058577; called by muse, mutect2, varscan2
- LRRC25 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100170553; called by muse, varscan2
- LSR | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV61554842; called by muse, mutect2, varscan2
- LYPD4 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV58027603; called by muse, mutect2, varscan2
- MAGEE1 | c.2690A>G p.Y897C | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV63909424; called by muse, mutect2, varscan2
- MAMSTR | c.782G>A p.G261E (on ENST00000318083 / NM_001130915.2; = p.G158E on NM_182574.2) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.056); catalogued as COSV58881014; called by muse, mutect2, varscan2
- MGAM | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV71884989; called by muse, mutect2, varscan2
- MNDA | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs867226822, COSV63740382; called by mutect2, varscan2
- MYO9A | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.164); catalogued as COSV61849227; called by muse, mutect2, varscan2
- NAA35 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV64484391; called by muse, mutect2, varscan2
- NDRG2 | c.856C>T p.L286F (on ENST00000298687 / NM_001354570.1; = p.L272F on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53872155; called by muse, mutect2, varscan2
- NLRP5 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV66763325; called by mutect2, varscan2
- NOL11 | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.622); catalogued as rs760153881, COSV53522770; called by mutect2, varscan2
- OR2L2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63549398, COSV63559425; called by muse, mutect2, varscan2
- OR2M2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV62897836, COSV62897885; called by muse, mutect2, varscan2
- OR4C15 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868092808, COSV58951930; called by muse, mutect2, varscan2
- OR4C3 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs1469699821, COSV60584517, COSV60587632; called by muse, mutect2, varscan2
- OR51A7 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV63788179; called by muse, varscan2
- OR8B2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV66664458, COSV66664578; called by muse, mutect2, varscan2
- P3H2 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077887; called by muse, mutect2, varscan2
- P3H2 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077890; called by muse, mutect2, varscan2
- PCDHA7 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.001); catalogued as COSV65335407; called by mutect2, varscan2
- PCDHB4 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs782620651, COSV52021200; called by mutect2, varscan2
- PCDHB5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as COSV50647190; called by muse, mutect2, varscan2
- PCDHGA1 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65295824; called by muse, mutect2, varscan2
- PCDHGC4 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.288); catalogued as COSV52747357; called by muse, mutect2, varscan2
- PCLO | c.12109G>A p.D4037N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV61625364; called by mutect2, varscan2
- PEG3 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV55629577; called by mutect2, varscan2
- PLA2G3 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53208044; called by muse, mutect2, varscan2
- PLA2G3 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99311828; called by muse, mutect2, varscan2
- PLA2G6 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.365); catalogued as COSV59273545; called by muse, mutect2, varscan2
- PRR14 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99788455; called by muse, mutect2, varscan2
- PSG2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 58/78 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs149747966; called by muse, mutect2, varscan2
- PTCH2 | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.991); catalogued as COSV64710459; called by muse, mutect2, varscan2
- PTCHD3 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV71256540; called by muse, mutect2, varscan2
- PTPRN2 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV67030751; called by muse, mutect2, varscan2
- RASGRP2 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62449128; called by muse, mutect2, varscan2
- RASGRP3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.282); catalogued as rs369611073; called by mutect2, varscan2
- RHOBTB2 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99311054; called by muse, mutect2, varscan2
- RPP40 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199844523, COSV100124155, COSV60291712; called by muse, mutect2, varscan2
- RUNX1T1 | c.496C>T p.H166Y (on ENST00000265814 / NM_001198628.1; = p.H139Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868452433, COSV56137692, COSV99752362; called by muse, varscan2
- RYR1 | c.6443C>T p.S2148F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62093526; called by muse, mutect2, varscan2
- SALL1 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 52/134 reads (39%) | catalogued as COSV51755478; called by muse, mutect2, varscan2
- SCN5A | c.5338G>A p.E1780K (on ENST00000333535 / NM_198056.3; = p.E1779K on NM_000335.5) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV61120261; called by muse, mutect2, varscan2
- SCN5A | c.4223G>A p.G1408E (on ENST00000333535 / NM_198056.3; = p.G1407E on NM_000335.5) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61120283; called by muse, mutect2
- SDK1 | c.4909C>T p.P1637S | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs1049264361, COSV67357012, COSV67362427; called by muse, varscan2
- SETD2 | c.4618T>C p.S1540P | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57433037; called by muse, mutect2, varscan2
- STAB2 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs758782387, COSV66336179; called by muse, mutect2, varscan2
- TENM1 | c.6340G>A p.E2114K | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV64428664; called by muse, mutect2, varscan2
- TMEM132B | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV54749505; called by muse, mutect2, varscan2
- TPD52L3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV58828136; called by muse, mutect2, varscan2
- TREM1 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55148167; called by muse, mutect2, varscan2
- TTN | c.82357G>A p.E27453K (on ENST00000591111; = p.E20029K on NM_003319.4) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | PolyPhen possibly damaging (0.607); catalogued as rs199501185; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- TTN | c.40829C>T p.S13610L (on ENST00000591111; = p.S6186L on NM_003319.4) | Missense Mutation (SNP) | VAF 67/137 reads (49%) | PolyPhen benign (0.049); catalogued as COSV59966371; called by muse, varscan2
- UBR1 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs764158113, CM117674, COSV51928090; called by muse, mutect2, varscan2
- UNC13C | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.823); catalogued as rs867213201, COSV52857496; called by muse, mutect2, varscan2
- USH2A | c.11558G>A p.G3853E | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100239922, COSV56349823, COSV56458370; called by muse, mutect2, varscan2
- WDR72 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV64743920; called by muse, mutect2, varscan2
- ZNF620 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.729); catalogued as rs753490375, COSV58820201; called by muse, mutect2, varscan2
- ZNF883 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1309485260, COSV71308982; called by muse, mutect2, varscan2
- ZNRF1 | c.656G>T p.R219I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57727868; called by mutect2, varscan2
- ABCC3 | c.468C>T p.I156= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs1290831674, COSV53319285; called by muse, mutect2, varscan2
- ABI3BP | c.1626C>T p.R542= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52532371; called by muse, mutect2, varscan2
- ACSBG2 | c.1350G>A p.K450= | Silent (SNP) | VAF 92/229 reads (40%) | catalogued as rs747990687, COSV53123722; called by muse, mutect2, varscan2
- ANK1 | c.3687G>A p.L1229= | Silent (SNP) | VAF 65/220 reads (30%) | catalogued as COSV55877754; called by mutect2, varscan2
- ASPM | c.2799C>T p.F933= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV54127578; called by muse, mutect2, varscan2
- C6 | c.1524G>A p.R508= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs562300050, COSV54706817, COSV54709914; called by muse, mutect2, varscan2
- CCDC85A | c.333C>T p.F111= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV68149260; called by muse, mutect2, varscan2
- CDH18 | c.1662G>A p.R554= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs970497849, COSV56912298; called by muse, mutect2, varscan2
- CRNN | c.600G>A p.R200= | Silent (SNP) | VAF 80/220 reads (36%) | catalogued as rs756485052, COSV55121371; called by muse, mutect2, varscan2
- CSF2RB | c.2391G>A p.G797= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV53256613; called by muse, mutect2, varscan2
- DGKH | c.1725C>T p.S575= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV54929907; called by muse, mutect2, varscan2
- DNAH2 | c.4860C>T p.T1620= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs749333128, COSV66718143; called by muse, mutect2, varscan2
- DOCK11 | c.5166C>T p.I1722= | Silent (SNP) | VAF 52/61 reads (85%) | catalogued as rs939756830, COSV52236166; called by muse, mutect2, varscan2
- DOCK4 | c.4830G>T p.V1610= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as rs771910846, COSV70233867, COSV70235090; called by muse, mutect2, varscan2
- GRIN2B | c.4338C>T p.I1446= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV74205404; called by muse, mutect2, varscan2
- GRM8 | c.2040G>A p.G680= | Silent (SNP) | VAF 52/86 reads (60%) | catalogued as COSV58806754; called by muse, mutect2, varscan2
- HIVEP3 | c.4248G>A p.L1416= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV56012746; called by mutect2, varscan2
- HSD17B1 | c.240G>A p.V80= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV56797521; called by mutect2, varscan2
- IFNL2 | c.318G>A p.L106= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV59593263; called by muse, varscan2
- IL23R | c.237G>A p.R79= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as rs368811377; called by muse, varscan2
- KCNJ10 | c.462C>T p.T154= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV63633234; called by muse, mutect2, varscan2
- MIPEP | c.1074C>T p.P358= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs759849788, COSV66300137; called by muse, mutect2, varscan2
- MUC16 | c.1881C>T p.L627= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV67456147, COSV67474768; called by mutect2, varscan2
- MUC5B | c.14272C>T p.L4758= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs373023004; called by muse, mutect2
- MYH1 | c.2256C>T p.S752= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs768131760, COSV56845945; called by muse, mutect2, varscan2
- MYH6 | c.354G>T p.S118= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100676718; called by mutect2, varscan2
- MYLK | c.543C>T p.S181= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV60607764; called by muse, mutect2, varscan2
- NIN | c.3462C>T p.D1154= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV55385161; called by muse, mutect2, varscan2
- NKTR | c.144C>T p.G48= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV51770687; called by muse, mutect2, varscan2
- NLRP7 | c.1953G>A p.P651= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs370874996, COSV60171329; called by muse, mutect2, varscan2
- OR10Z1 | c.603C>T p.I201= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as COSV63524312; called by muse, mutect2, varscan2
- OR2W3 | c.186C>T p.F62= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV64456507; called by muse, mutect2, varscan2
- OR51B5 | c.144G>A p.K48= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV56175137, COSV56176498; called by muse, mutect2, varscan2
- OR51Q1 | c.630C>T p.I210= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs773847387, COSV56178359; called by muse, mutect2, varscan2
- PATZ1 | c.420C>T p.A140= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs995060652, COSV53229057; called by muse, mutect2, varscan2
- PCDHB1 | c.1725C>T p.D575= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV60630137; called by muse, mutect2, varscan2
- PDZD4 | c.594C>T p.I198= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV51245946; called by muse, mutect2, varscan2
- PRR14 | c.957C>T p.T319= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99788452; called by muse, mutect2, varscan2
- SMAD2 | c.27G>T p.P9= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs546743584, COSV50992824, COSV51072677; called by mutect2, varscan2
- TENM3 | c.57G>A p.K19= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV69303491; called by muse, mutect2, varscan2
- TIE1 | c.1509C>T p.N503= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs550712048, COSV65249084; called by mutect2, varscan2
- TRAK1 | c.396C>T p.I132= (on ENST00000327628 / NM_001349247.2; = p.I74= on NM_014965.5) | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as rs1294293329, COSV58257221; called by muse, mutect2, varscan2
- TRAPPC9 | c.2481C>T p.V827= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as rs747013383, COSV66896298; called by muse, mutect2, varscan2
- TXN2 | c.94C>T p.L32= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV53397305; called by muse, mutect2, varscan2
- VIL1 | c.1617C>T p.F539= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV50286523; called by muse, mutect2, varscan2
- WRAP73 | c.699C>T p.P233= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1326280477, COSV54560664; called by muse, mutect2, varscan2
- ZNF304 | c.498C>T p.S166= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs755148887, COSV56583852; called by muse, mutect2, varscan2
- ZNF331 | c.300C>T p.V100= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV53475906; called by muse, mutect2, varscan2
- AC024940.1 | n.319C>T | RNA (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- ANAPC11 | c.-1C>T | 5'UTR (SNP) | VAF 23/72 reads (32%) | catalogued as rs775127831, COSV100485862; called by muse, mutect2, varscan2
- MTSS1 | c.1036-873G>A | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100275078; called by muse, mutect2, varscan2
- SNORD113-9 | n.39G>A | RNA (SNP) | VAF 81/135 reads (60%) | called by muse, mutect2, varscan2
